Somatic mutation profile of tumor specimen MP2PRT-PAUUGC-TMP1-A (aliquot MP2PRT-PAUUGC-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUUGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,701 days).
Specimen MP2PRT-PAUUGC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64adcede-3cd4-4896-bc23-0e4fcb3f667b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUGC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUGC-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24c7316e-c356-42f3-9263-dff033eae8a4

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, In Frame Ins 2, Nonsense Mutation 2, Intron 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN1A1 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 15/524 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333046619, COSV55066748; called by muse, mutect2
- CRYBG3 | c.6568G>A p.V2190I | Missense Mutation (SNP) | VAF 165/366 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs768639623, COSV51713764, COSV99476741; called by muse, mutect2, varscan2
- GLRA1 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781570584, CM1514335, COSV51014568; called by muse, mutect2, varscan2
- MIA2 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); catalogued as COSV54488376; called by muse, mutect2
- MMP9 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 36/756 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769280932; called by muse, mutect2
- OBSL1 | c.5228C>T p.S1743L | Missense Mutation (SNP) | VAF 52/1061 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs944701875, COSV104373022; called by muse, mutect2
- PCBP1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100340072; called by muse, mutect2, varscan2
- TRIM71 | c.2363G>A p.G788D | Missense Mutation (SNP) | VAF 32/582 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101070535; called by muse, mutect2
- CAMSAP3 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 278/595 reads (47%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.348_349insGGGGGG p.A116_R117insGG | In Frame Ins (INS) | VAF 43/71 reads (61%) | called by pindel, varscan2
- IGHV4-61 | c.355_356insGTGCCTCTGGGGGAG | In Frame Ins (INS) | VAF 42/49 reads (86%) | called by pindel, varscan2*
- KRT79 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 209/542 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- NCOR2 | c.5051C>G p.T1684S | Missense Mutation (SNP) | VAF 398/868 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NTN1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 226/637 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLCE1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 17/437 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PRAMEF20 | c.1134G>C p.E378D | Missense Mutation (SNP) | VAF 25/678 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- RECQL4 | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 340/747 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SHF | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 39/866 reads (5%) | called by muse, mutect2
- SLC9C2 | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- SOCS6 | c.518dup p.D174Gfs*8 | Frame Shift Ins (INS) | VAF 201/488 reads (41%) | called by mutect2, pindel, varscan2
- ZNF701 | c.1123C>G p.Q375E (on ENST00000301093; = p.Q309E on NM_018260.3) | Missense Mutation (SNP) | VAF 9/316 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- ZNF71 | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 370/755 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- IGHV1-58 | c.321C>T p.S107= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs911072372; called by muse, varscan2
- IGHV4-59 | c.349_350delinsCATGAC p.*117delinsHD | Silent (INS) | VAF 10/36 reads (28%) | called by pindel, varscan2*
- PCF11 | c.174C>T p.I58= | Silent (SNP) | VAF 18/404 reads (4%) | catalogued as COSV100019487; called by muse, mutect2
- IFT46 | c.46-772C>T | Intron (SNP) | VAF 24/556 reads (4%) | called by muse, mutect2
- IGHV1-69 | chr14:106714683 ins TGCCCCCAACA | 3'Flank (INS) | VAF 23/48 reads (48%) | called by pindel, varscan2
